Somatic mutation profile of tumor specimen TCGA-JY-A6FB-01A (aliquot TCGA-JY-A6FB-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.4 years (28,269 days).
Specimen TCGA-JY-A6FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c2da44-f34a-43b4-a700-7ee3b6a01588.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FB-10A (Blood Derived Normal), aliquot TCGA-JY-A6FB-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/906319f5-fe90-4aac-8e5d-d3d0e3ed3075

The open-access MAF lists 92 somatic variants for this specimen: 63 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 27, Frame Shift Ins 6, Nonsense Mutation 5, Splice Site 2, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 23/39 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6080C>T p.A2027V (on ENST00000614293; = p.A1997V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs573640596, COSV55802592; called by muse, mutect2, varscan2
- ADAM12 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs750526567; called by muse, mutect2, varscan2
- ADAMTS8 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369424623, COSV57298542; called by muse, mutect2, varscan2
- ARHGAP9 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1316662808, COSV62723624; called by muse, mutect2, varscan2
- ARID1B | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs544895806, COSV51651464; called by muse, mutect2, varscan2
- C8orf74 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs138207063, COSV58755266; called by muse, mutect2, varscan2
- CEP95 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs781934920; called by muse, varscan2
- DCDC1 | c.4967A>G p.K1656R (on ENST00000597505 / NM_001367979.1; = p.K763R on NM_020869.3) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1565036850; called by muse, mutect2, varscan2
- DCT | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs751146188, COSV65467948; called by muse, mutect2, varscan2
- DCX | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100576793; called by muse, mutect2, varscan2
- DVL3 | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.038); catalogued as rs773837677; called by mutect2, varscan2
- FRMPD1 | c.3082G>T p.A1028S | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as COSV100899549; called by muse, mutect2, varscan2
- HERC2 | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as rs781731609, COSV55321995; called by muse, mutect2, varscan2
- LAMA1 | c.8695G>A p.G2899R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369240094, COSV67532592; called by muse, mutect2, varscan2
- MEX3C | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as rs533957172; called by muse, mutect2, varscan2
- OR6C3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.063); catalogued as rs1355193158, COSV104428267; called by muse, mutect2, varscan2
- PDP1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52601073; called by muse, mutect2, varscan2
- PLD5 | c.1120C>T p.R374* (on ENST00000442594; = p.R312* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 83/107 reads (78%) | catalogued as rs367992813; called by muse, mutect2, varscan2
- PLXNA4 | c.3109G>A p.V1037M | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs1480963183; called by muse, mutect2, varscan2
- PLXND1 | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60709219; called by muse, mutect2, varscan2
- RAX | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV56874734; called by muse, mutect2, varscan2
- RBP3 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1375634622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACM1L | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs745878798; called by muse, mutect2, varscan2
- SIGLEC9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs780555801; called by muse, mutect2, varscan2
- SMARCA4 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227826852, COSV60788496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SST | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55031330; called by muse, mutect2, varscan2
- TMEM175 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140262376; called by muse, mutect2, varscan2
- XDH | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV65151108; called by muse, mutect2, varscan2
- ABCB6 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- AIRE | c.133-1G>T p.X45_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- BUB1B | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL19A1 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB1 | c.1464dup p.S489Qfs*16 (on ENST00000617958; = p.S424Qfs*16 on NM_030594.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- CPS1 | c.3480+1G>T p.X1160_splice | Splice Site (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1059del p.E354Kfs*6 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- CYP4F3 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FRMD4A | c.1832G>A p.W611* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GPRIN3 | c.1553_1567del p.I518_H523delinsN | In Frame Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- GSDMC | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GTPBP10 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSPG2 | c.170_173dup p.D58Efs*6 | Frame Shift Ins (INS) | VAF 14/26 reads (54%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.3205G>C p.V1069L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MMEL1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MUC16 | c.27674T>C p.M9225T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIBAN2 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR6Y1 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- POGK | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RBL2 | c.2125G>C p.V709L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX2 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SCN11A | c.3501_3503del p.V1168del | In Frame Del (DEL) | VAF 12/34 reads (35%) | called by pindel, varscan2
- SCN7A | c.2888delinsTA p.T963Ifs*3 | Frame Shift Ins (INS) | VAF 8/53 reads (15%) | called by pindel, varscan2*
- SCRIB | c.2213T>C p.L738P | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SESTD1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- SPHK2 | c.520_526del p.P174Cfs*32 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- STN1 | c.347_350dup p.Q117Hfs*6 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- SYDE1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.7357T>G p.L2453V (on ENST00000367255 / NM_182961.4; = p.L2460V on NM_033071.3) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TYRO3 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- USP6NL | c.672dup p.V225Cfs*6 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- UTY | c.3208G>C p.G1070R | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- AL136295.1 | c.1392C>T p.V464= | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- BCL11B | c.417G>A p.E139= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV61732974; called by muse, mutect2, varscan2
- CASKIN1 | c.198C>T p.S66= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs746187410; called by mutect2, varscan2
- CC2D2A | c.1176G>A p.Q392= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV67504299; called by muse, mutect2, varscan2
- CEP112 | c.1539C>G p.V513= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, varscan2
- CLRN2 | c.381G>A p.P127= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs374029760; called by muse, mutect2, varscan2
- DCC | c.3939G>T p.L1313= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- DDX51 | c.1330C>T p.L444= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs888388758; called by muse, mutect2, varscan2
- DOCK4 | c.3351G>A p.L1117= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs548719991; called by muse, mutect2, varscan2
- EIF3B | c.1734T>C p.A578= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs779376781; called by muse, mutect2, varscan2
- FAM71E1 | c.672C>T p.F224= (on ENST00000600100 / NM_001308429.2; = p.F208= on NM_138411.3) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs761365225, COSV63093076; called by muse, mutect2, varscan2
- GABRG3 | c.846G>A p.T282= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs756924937, COSV100408290; called by muse, mutect2, varscan2
- HS3ST3B1 | c.708G>A p.S236= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs754524924; called by muse, mutect2, varscan2
- MAGEE1 | c.108C>T p.L36= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as rs1556839107; called by muse, mutect2, varscan2
- MAPK15 | c.735C>T p.L245= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs147473272; called by muse, mutect2, varscan2
- MYH6 | c.267C>T p.D89= | Silent (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- NAGPA | c.853C>T p.L285= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- NCOR2 | c.6336G>A p.S2112= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs747314164; called by mutect2, varscan2
- PCDHB2 | c.774C>T p.P258= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs782011952, COSV52031011; called by muse, mutect2, varscan2
- PLCE1 | c.4471T>C p.L1491= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs773520472; called by muse, mutect2, varscan2
- RBM11 | c.402A>G p.L134= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV68748417; called by muse, mutect2, varscan2
- RPL4 | c.1071A>C p.A357= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- RPS3A | c.45G>A p.K15= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- RUFY3 | c.786C>T p.D262= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- TIMELESS | c.2445C>T p.S815= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs760450039; called by muse, mutect2, varscan2
- TRPV6 | c.688C>A p.R230= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs199768684; called by muse, mutect2, varscan2
- ZNF513 | c.69C>T p.D23= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs1269272359; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149795 C>T | 5'Flank (SNP) | VAF 10/37 reads (27%) | catalogued as rs372988572; called by muse, mutect2, varscan2
- CSF2RA | c.*36G>A | 3'UTR (SNP) | VAF 77/222 reads (35%) | catalogued as rs144367097, COSV62625342; called by muse, mutect2, varscan2
